Somatic mutation profile of tumor specimen MP2PRT-PAPJHM-TMP1-A (aliquot MP2PRT-PAPJHM-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPJHM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (846 days).
Specimen MP2PRT-PAPJHM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0df2da3-45c0-4f60-bb0e-b96d9ae9a3d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPJHM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPJHM-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53aa15ba-1d12-4cbc-8d8d-4c1b8c1e38c2

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 12, Silent 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AVIL | c.1239A>T p.Q413H | Missense Mutation (SNP) | VAF 33/427 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV57682471; called by muse, mutect2
- CTNND2 | c.472C>T p.L158F | Missense Mutation (SNP) | VAF 66/299 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1275104746; called by muse, mutect2, varscan2
- DMD | c.7570C>T p.R2524C | Missense Mutation (SNP) | VAF 67/337 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as rs886043732, COSV58906820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM189A2 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 41/394 reads (10%) | catalogued as rs765227517; called by muse, mutect2, varscan2
- FGFRL1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 196/560 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); catalogued as rs757739388, COSV99294442; called by muse, mutect2, varscan2
- JPH1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 49/644 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV60608583; called by muse, mutect2
- LAMA5 | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs746800398; called by muse, mutect2, varscan2
- OR8S1 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100043449, COSV59601001; called by muse, mutect2
- PRKAG1 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60291524; called by muse, mutect2
- AXIN2 | c.2198G>A p.G733E | Missense Mutation (SNP) | VAF 83/360 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- DMRTB1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 267/565 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, varscan2
- H1-3 | c.232A>T p.N78Y | Missense Mutation (SNP) | VAF 203/417 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ROS1 | c.5647C>A p.H1883N | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- COL5A3 | c.375G>A p.A125= | Silent (SNP) | VAF 42/594 reads (7%) | catalogued as rs1458077537; called by muse, mutect2
- HDAC5 | c.3060G>A p.S1020= | Silent (SNP) | VAF 126/321 reads (39%) | catalogued as rs376041842; called by muse, mutect2, varscan2
- HOMER2 | c.573G>A p.R191= (on ENST00000304231 / NM_199330.3; = p.R180= on NM_004839.4) | Silent (SNP) | VAF 44/530 reads (8%) | called by muse, mutect2
- HSD17B13 | c.222G>A p.E74= | Silent (SNP) | VAF 39/368 reads (11%) | called by muse, mutect2, varscan2
- MGA | c.6717T>C p.T2239= (on ENST00000219905 / NM_001164273.1; = p.T2030= on NM_001080541.2) | Silent (SNP) | VAF 63/321 reads (20%) | called by muse, mutect2, varscan2
- MON1A | c.1386G>A p.T462= | Silent (SNP) | VAF 44/457 reads (10%) | called by muse, mutect2
- ZC3H15 | c.567C>T p.N189= | Silent (SNP) | VAF 73/345 reads (21%) | called by muse, mutect2, varscan2
